Gene-level copy-number profile of tumor specimen TCGA-24-1927-01A from TCGA case TCGA-24-1927, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.5 years (21,719 days).
Specimen TCGA-24-1927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5c90d04e-2693-49ce-bf06-79de908598d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1927-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6118cdbd-ca45-4d4a-b200-31c2292b1480

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 15,175; copy number 2: 36,397; copy number 3: 7,077; copy number 4: 1,029; copy number 5: 32; copy number 9: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1927-01A-01D-0648-01): tumor purity 0.82, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,314,500–115,147,288, 1 gene (within-gene range 0–1): ZBTB20.
- chr3:114,351,771–114,876,514, 5 genes (within-gene range 0–1): ZBTB20-AS1, ZBTB20-AS5, ZBTB20-AS2, MIR4796, ZBTB20-AS3.
- chr6:108,986,437–109,355,063, 5 genes (within-gene range 0–1): SESN1, AL390208.1, RNU6-653P, CEP57L1, CCDC162P.
- chr8:17,643,795–17,800,917, 4 genes (within-gene range 0–1): MTUS1, MIR548V, AC124069.1, RNA5SP256.
- chr8:17,808,361–17,822,183, 1 gene: AC027117.1.
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,316,863–48,444,704, 4 genes (within-gene range 0–1): PPP1R26P1, PCNPP5, AL392048.1, LPAR6.
- chr13:109,915,096–109,915,420, 1 gene: RN7SKP10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 107 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,848,276–9,910,336, 1 gene, copy number 5 (within-gene range 3–5): CTNNBIP1.
- chr1:9,900,614–10,630,758, 29 genes, copy number 5: AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P.
- chr16:6,380,476–6,577,359, 2 genes, copy number 5: AC006112.1, AC007223.1.
- chr16:35,068,211–35,912,516, 75 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
